Somatic mutation profile of tumor specimen TARGET-10-PARTZE-09A (aliquot TARGET-10-PARTZE-09A-01D) from TARGET case TARGET-10-PARTZE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.5 years (4,551 days).
Specimen TARGET-10-PARTZE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c6aa08e-6e7e-4e6e-a323-1bec9a26e005.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTZE-10A (Blood Derived Normal), aliquot TARGET-10-PARTZE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c98cc43-77e7-460d-9861-e223fc2c585d

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CR2 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as rs759786703, COSV65506396; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC39A6 | c.1726C>T p.H576Y | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52369108; called by muse, mutect2, varscan2
- GALNT9 | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- HSP90AA1 | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGED2 | c.1417G>C p.A473P | Missense Mutation (SNP) | VAF 53/56 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SCAP | c.2468G>A p.G823D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2
- SYTL4 | c.911T>A p.M304K | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT tolerated (0.29); PolyPhen benign (0.03); called by muse, mutect2
- FZD8 | c.1827G>A p.T609= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs1409902788; called by muse, mutect2
- OR12D3 | c.180T>C p.F60= | Silent (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- AL109618.1 | n.884A>C | RNA (SNP) | VAF 53/98 reads (54%) | called by muse, mutect2, varscan2
- SLC2A13 | c.1034+113dup | Intron (INS) | VAF 6/19 reads (32%) | called by mutect2, pindel, varscan2
